TCGA case TCGA-06-2563 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ba383ea6-c885-49f0-bddc-e00be0230a6b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 72 years; Vital status: Alive.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 72.9 years (26,643 days); Year of diagnosis: 2009; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 27 days; Days to treatment end: 57 days; Treatment dose: 46 cGy; Number of fractions: 23; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 27 days; Days to treatment end: 57 days; Number of cycles: 1; Treatment dose: 120 mg; Prescribed dose: 75; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Initial disease status: Progressive Disease; Days to treatment start: 566 days (1.5 years); Days to treatment end: 576 days (1.6 years); Treatment dose: 3,200 cGy; Course number: 2; Number of fractions: 4; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Gamma-Secretase Inhibitor RO4929097; Initial disease status: Progressive Disease; Days to treatment start: 885 days (2.4 years); Days to treatment end: 931 days (2.5 years); Number of cycles: 2; Treatment dose: 20 mg/day; Prescribed dose: 20; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 934 days (2.6 years); Treatment dose: 549 mg; Treatment outcome: Treatment Ongoing; Prescribed dose: 10; Prescribed dose units: mg/kg; Route of administration: Intravenous.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 74.5 years (27,197 days); Days to diagnosis: 554 days (1.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.

Follow-up (5 entries)
- Days to follow up: 259 days; Disease response: With Tumor.
- Day 554 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 932 days (2.6 years); Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Preoperative.
- Karnofsky performance status: 70; Timepoint: Post Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-2563-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2.5; Intermediate dimension: 0.8; Shortest dimension: 0.8.
  Slide TCGA-06-2563-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
  Slide TCGA-06-2563-01A-01-BS1: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
- Sample TCGA-06-2563-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Pharmaceutical therapy drug name: Temodar.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Regimen number: 03; Therapy regimen: Progression.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 3: Regimen number: 02; Pharmaceutical therapy drug name: R04929097; Therapy regimen: Progression.
- Radiation treatment 2: Radiation type other: Fractionated stereotactic radiosurgery; Therapy regimen: Progression.
- Follow-up form 2: Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.
- Follow-up form 2, New tumor event: New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 932 days; disease-specific survival: no event (censored), 932 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 554 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-06-2563-01A-01D-0784-01): tumor purity 0.85, ploidy 2.05, whole-genome doublings 0.
